Somatic mutation profile of tumor specimen MMRF_1917_1_BM_CD138pos (aliquot MMRF_1917_1_BM_CD138pos_T1_KBS5U_L06428) from MMRF case MMRF_1917, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.6 years (19,948 days).
Specimen MMRF_1917_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc7c002c-c30b-453d-90dc-e46f622490e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1917_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1917_1_PB_Whole_C3_KBS5U_L06473; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a556d5d4-1d16-45ae-b987-9570bde3fadd

The open-access MAF lists 146 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 40, Intron 18, Silent 17, 5'UTR 11, Nonsense Mutation 4, 5'Flank 3, RNA 3, Splice Region 2, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADORA1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV55143635; called by muse, mutect2
- ATRN | c.3814C>T p.Q1272* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV53528038; called by muse, mutect2, varscan2
- CACNG7 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs369839062, COSV99712202; called by muse, mutect2, varscan2
- CYBB | c.816G>C p.W272C | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as CM960446; called by muse, mutect2
- FAM186A | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV59245690; called by muse, mutect2
- FRMD6 | c.956A>G p.N319S (on ENST00000344768 / NM_001267046.2; = p.N311S on NM_152330.4) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs1437596568; called by muse, mutect2
- IGHV3-13 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs111423442; called by muse, varscan2
- IGKV4-1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs148071875; called by muse, varscan2
- IGLV3-1 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs142180628; called by muse, varscan2
- INTS14 | c.1330G>A p.A444T (on ENST00000313182 / NM_001366360.2; = p.A365T on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777498623, COSV56013133; called by muse, mutect2, varscan2
- IPCEF1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1377979624, COSV54544646; called by muse, mutect2, varscan2
- METTL17 | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1017452497; called by muse, mutect2, varscan2
- MYT1L | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101219200, COSV67733063; called by muse, mutect2, varscan2
- NAV3 | c.4418G>C p.G1473A | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV57071519; called by muse, mutect2
- PTEN | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM1211213, COSV64291845, COSV64293372, COSV64295066; called by muse, mutect2, varscan2
- SASH1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as rs765761559, COSV66561400; called by muse, mutect2
- SLC1A1 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1363317309; called by muse, mutect2
- SLC27A3 | c.424C>T p.P142S (on ENST00000271857; = p.P14S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as rs769930407; called by muse, mutect2, varscan2
- TAS1R1 | c.2494C>G p.Q832E | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59839719; called by muse, mutect2
- TRAF2 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV56039440; called by muse, mutect2
- TRIB2 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50226149; called by muse, mutect2
- ZNF155 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as rs1341338641; called by muse, mutect2, varscan2
- ANGEL1 | c.1619-6C>T | Splice Region (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- ARMH1 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP9B | c.1334T>C p.I445T | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CC2D2A | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CHD2 | c.3916C>T p.Q1306* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- CRACD | c.1757C>G p.P586R | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP27A1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ESX1 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- FZD1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2
- IGHV3-13 | c.89T>C p.L30S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); called by muse, varscan2
- IMMT | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- KATNAL2 | c.1100+1G>A p.X367_splice (on ENST00000356157 / NM_001353899.1; = p.X295_splice on NM_031303.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- KIF1C | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.175); called by muse, mutect2
- KMT2A | c.8951C>G p.T2984S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTR1 | c.104_105del p.S35* | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- MIR29B2CHG | n.125G>A | Splice Region (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- NAV1 | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2
- OBSCN | c.11186A>T p.D3729V | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- OR1S2 | c.499A>T p.I167F | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.305); called by muse, mutect2
- PHLPP1 | c.1980A>C p.Q660H | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- POLR2A | c.2958G>A p.M986I | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2
- PPAN-P2RY11 | c.205T>A p.S69T | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PXYLP1 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2
- RAB8A | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- REC8 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SBF2 | c.2124T>A p.Y708* | Nonsense Mutation (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1777A>G p.K593E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRT | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDR62 | c.1830_1834del p.Q611Gfs*21 | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- WRNIP1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- YLPM1 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 8/249 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2
- ADGRE5 | c.474C>T p.C158= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as rs1483871693; called by muse, mutect2
- CDH20 | c.1962C>T p.D654= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs997964400; called by muse, mutect2, varscan2
- CEP290 | c.5193G>A p.K1731= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- CLDN5 | c.498C>A p.I166= (on ENST00000618236 / NM_001363066.2; = p.I251= on NM_003277.4) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs774155075; called by muse, mutect2, varscan2
- COL1A1 | c.246C>A p.P82= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as CD042191; called by muse, mutect2, varscan2
- DUSP28 | c.411C>T p.R137= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as rs373547730; called by muse, mutect2, varscan2
- FEZ2 | c.810G>A p.Q270= | Silent (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
- IGHV3-33 | c.210A>C p.I70= | Silent (SNP) | VAF 100/124 reads (81%) | catalogued as rs371646544; called by muse, mutect2, varscan2
- IGLV3-1 | c.288C>G p.T96= | Silent (SNP) | VAF 74/103 reads (72%) | catalogued as rs555994283; called by muse, varscan2
- KIAA0825 | c.2253T>C p.F751= | Silent (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- LAMA1 | c.5829G>A p.A1943= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs779914431, COSV67532571; called by muse, mutect2, varscan2
- MACF1 | c.1398G>A p.P466= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs746529212; called by muse, mutect2, varscan2
- MUC17 | c.5646T>G p.S1882= | Silent (SNP) | VAF 121/325 reads (37%) | catalogued as rs767903717; called by muse, mutect2, varscan2
- NLRP12 | c.1395G>A p.A465= | Silent (SNP) | VAF 50/131 reads (38%) | called by muse, mutect2, varscan2
- POLR1A | c.3120G>A p.L1040= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- PRICKLE2 | c.2586C>T p.S862= (on ENST00000295902; = p.S806= on NM_198859.4) | Silent (SNP) | VAF 67/146 reads (46%) | catalogued as rs1247326386, COSV55765047; called by muse, mutect2, varscan2
- SLC10A3 | c.925C>T p.L309= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38477G>A | Intron (SNP) | VAF 3/35 reads (9%) | catalogued as rs1454460801; called by muse, mutect2
- AP000769.5 | chr11:65499227 G>A | 5'Flank (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- APOL2 | c.*847A>T | 3'UTR (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- ARID4B | c.2125+3908A>G | Intron (SNP) | VAF 36/65 reads (55%) | catalogued as rs547986869; called by muse, mutect2, varscan2
- ARL5B | c.*4511G>A | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- CACNA2D1 | c.879+9935G>A | Intron (SNP) | VAF 8/150 reads (5%) | catalogued as rs958831923; called by muse, mutect2
- CELSR1 | c.*2013G>T | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- CMTR1 | c.*601C>T | 3'UTR (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2, varscan2
- CSNK1D | c.1197+119T>C | Intron (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- DHX8 | chr17:43526467 T>C | 3'Flank (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2
- DTX1 | c.-235G>C | 5'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- FAM122B | c.*1563C>G | 3'UTR (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- FAM133A | c.*941A>T | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- FIGN | c.*1008A>C | 3'UTR (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- FRMD1 | c.*526G>A | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+17825A>C | Intron (SNP) | VAF 57/109 reads (52%) | called by muse, mutect2, varscan2
- GABRG1 | c.*1769C>A | 3'UTR (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- GDNF | c.*2012G>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs1354214868; called by muse, mutect2
- GJB7 | c.*389_*392del | 3'UTR (DEL) | VAF 3/37 reads (8%) | catalogued as rs1201641185, COSV51531576; called by pindel, varscan2*
- GOPC | c.*2959_*2962del | 3'UTR (DEL) | VAF 14/61 reads (23%) | called by pindel, varscan2
- GPX1P1 | n.523C>T | RNA (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- HAPLN1 | c.*1191C>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- HNRNPLL | c.*1641C>G | 3'UTR (SNP) | VAF 9/117 reads (8%) | catalogued as rs1009793071; called by muse, mutect2
- IGLL5 | c.-38G>A | 5'UTR (SNP) | VAF 45/48 reads (94%) | catalogued as rs558520048, COSV73249446; called by muse, mutect2, varscan2
- IGLV3-21 | c.-37C>T | 5'UTR (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- IL18R1 | c.*1672A>G | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- INTS9 | chr8:28890113 C>T | 5'Flank (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- ITGA9 | c.*3551G>T | 3'UTR (SNP) | VAF 59/137 reads (43%) | called by muse, mutect2, varscan2
- JCAD | c.*4408C>T | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- KIZ | c.1924+53C>G | Intron (SNP) | VAF 36/42 reads (86%) | catalogued as rs934868722; called by muse, varscan2
- KRAS | c.*15_*17del | 3'UTR (DEL) | VAF 14/70 reads (20%) | called by pindel, varscan2
- LEKR1 | c.264-32260C>T | Intron (SNP) | VAF 7/193 reads (4%) | called by muse, mutect2
- LINC00943 | n.1232-49T>C | Intron (SNP) | VAF 98/218 reads (45%) | called by muse, mutect2, varscan2
- LSS | c.1989-686T>G | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs1247763394; called by muse, mutect2, varscan2
- MAFB | c.*85T>G | 3'UTR (SNP) | VAF 44/77 reads (57%) | called by muse, mutect2
- MAFB | c.*83T>G | 3'UTR (SNP) | VAF 43/76 reads (57%) | called by muse, mutect2
- METTL3 | c.-100C>T | 5'UTR (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- MROH2B | c.-89A>C | 5'UTR (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- MTMR2 | c.80+23C>T | Intron (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- MYO1E | c.-188T>C | 5'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- MYT1 | c.*516A>T | 3'UTR (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- N4BP3 | c.*389C>A | 3'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- NEDD8 | c.19-100T>C | Intron (SNP) | VAF 15/122 reads (12%) | catalogued as rs1031186608; called by muse, mutect2, varscan2
- NOP9 | c.*3592C>G | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- PGBD5 | c.-13C>T | 5'UTR (SNP) | VAF 20/316 reads (6%) | catalogued as rs536446909; called by muse, mutect2
- PI4K2B | c.*940T>G | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- PKD1L2 | n.4693C>T | RNA (SNP) | VAF 15/94 reads (16%) | catalogued as rs747962383; called by muse, mutect2, varscan2
- PLCB1 | c.*1734T>C | 3'UTR (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- RAB3IP | c.*1494C>T | 3'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- RGP1 | c.-67G>A | 5'UTR (SNP) | VAF 7/71 reads (10%) | catalogued as rs1345533626; called by muse, varscan2
- RIMS2 | c.699-4754G>C | Intron (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- RNF114 | c.*864A>G | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- SC5D | c.*587C>T | 3'UTR (SNP) | VAF 33/70 reads (47%) | catalogued as rs1204914933; called by muse, mutect2, varscan2
- SDE2 | c.*909C>T | 3'UTR (SNP) | VAF 14/102 reads (14%) | catalogued as rs902973136; called by muse, mutect2, varscan2
- SDR16C6P | n.168T>C | RNA (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- SEC62 | c.*5023A>C | 3'UTR (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- SEMA3F | c.*955A>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+8425G>A | Intron (SNP) | VAF 42/46 reads (91%) | catalogued as rs1555809468; called by muse, mutect2, varscan2
- SKIDA1 | c.-1240T>G | 5'UTR (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- SLC16A2 | c.*1922G>A | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SLC52A2 | c.-110-56C>G | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as rs371747832; called by muse, mutect2
- SLCO3A1 | c.*1984C>A | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- SPINK5 | c.411-111A>T | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- SVOP | c.*774G>A | 3'UTR (SNP) | VAF 4/64 reads (6%) | catalogued as rs924030197; called by muse, mutect2
- TAP1 | c.2221-43T>C | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- TECPR2 | c.*2809G>A | 3'UTR (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- TRIM66 | c.*2598G>C | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TRIML2 | c.-190G>T | 5'UTR (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- TYW5 | c.*2339C>A | 3'UTR (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- WDR37 | c.726+255C>T | Intron (SNP) | VAF 13/147 reads (9%) | called by muse, mutect2
- ZCCHC3 | c.*153C>T | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.*521T>G | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-334del | 5'UTR (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- ZMIZ2 | c.*1614G>A | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- ZNF436 | c.-60-26C>T | Intron (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- ZWILCH | chr15:66505104 C>T | 5'Flank (SNP) | VAF 15/66 reads (23%) | called by muse, varscan2
